MMRF case MMRF_1433 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/42eb09c6-6769-4818-be02-12667a4b0693

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 55 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 55.8 years (20,373 days); ISS stage: I; Days to last known disease status: 1,429 days (3.9 years); Days to last follow up: 1,429 days (3.9 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 65 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 68 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 95 days; Days to treatment end: 95 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 120 days; Days to treatment end: 120 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 122 days; Days to treatment end: 122 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 256 days; Days to treatment end: 256 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 257 days; Days to treatment end: 257 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 257 days; Days to treatment end: 257 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 883 days (2.4 years); Days to treatment end: 1,082 days (3.0 years).
   Treatment given: Therapeutic agents: Dexamethasone + Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,100 days (3.0 years); Days to treatment end: 1,332 days (3.6 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide + Other; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,359 days (3.7 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,429.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 3.77 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.607 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 10.2 mg/dL; Immunoglobulin G 50.9 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 2.12 µg/mL; Lactate Dehydrogenase 1.83 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 35 g/L; Total Protein 9.5 g/dL; Glucose 4.95 mmol/L.
- Day 114 (ECOG 0): M Protein 1.49 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.669 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.25 mg/dL; Immunoglobulin G 18 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 2.44 µg/mL; Lactate Dehydrogenase 7.55 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 7.5 g/dL; Glucose 5.45 mmol/L.
- Day 184 (ECOG 0): M Protein 0.75 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.78 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 45 g/L; Total Protein 7 g/dL; Glucose 4.68 mmol/L.
- Day 289 (ECOG 1): M Protein 0.52 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.15 mg/dL; Immunoglobulin G 9.75 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.6 g/L; Beta 2 Microglobulin 4.05 µg/mL; Hemoglobin 7.44 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.06 mmol/L.
- Day 348 (ECOG 0): M Protein 0.48 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 1.78 µg/mL; Hemoglobin 9.05 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 46 g/L; Total Protein 7.1 g/dL; Glucose 5.12 mmol/L.
- Day 466 (ECOG 0): M Protein 0.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 9.54 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 4.9 mmol/L.
- Day 562 (ECOG 0): M Protein 0.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 8.69 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 6.8 g/dL; Glucose 4.84 mmol/L.
- Day 660 (ECOG 1): M Protein 0.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.43 mmol/L; Albumin 40.9 g/L; Total Protein 6.8 g/dL; Glucose 4.73 mmol/L.
- Day 739 (ECOG 0): Lactate Dehydrogenase 6.17 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 5.17 mmol/L.
- Day 809 (ECOG 0): Lactate Dehydrogenase 6.27 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 5.23 mmol/L.
- Day 883 (ECOG 0): M Protein 1.75 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.623 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.26 mg/dL; Immunoglobulin G 22.6 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.98 µg/mL; Lactate Dehydrogenase 6.58 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 302 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 7.6 g/dL; Glucose 5.17 mmol/L.
- Day 1,002 (ECOG 0): M Protein 0.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.799 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.81 mg/dL; Immunoglobulin G 5.63 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 1.79 µg/mL; Lactate Dehydrogenase 6.95 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 6 g/dL; Glucose 5.01 mmol/L.
- Day 1,051 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.63 mg/dL; Immunoglobulin G 5.68 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 7.62 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 6.1 g/dL; Glucose 4.73 mmol/L.
- Day 1,126 (ECOG 0): M Protein 0.82 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.86 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 6.08 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 271 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.9 g/dL; Glucose 5.45 mmol/L.
- Day 1,240 (ECOG 0): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.171 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 19.5 mg/dL; Immunoglobulin G 17.3 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 6.15 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 257 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 34 g/L; Total Protein 6.3 g/dL; Glucose 5.12 mmol/L.
- Day 1,345 (ECOG 0): M Protein 2.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 21.2 mg/dL; Immunoglobulin G 27.5 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 2.21 µg/mL; Lactate Dehydrogenase 8.5 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.53 mmol/L; Albumin 43 g/L; Total Protein 8.6 g/dL; Glucose 5.17 mmol/L.
- Day 1,415 (ECOG 0): M Protein 1.92 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.128 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 23.5 mg/dL; Immunoglobulin G 23.2 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 2.05 µg/mL; Lactate Dehydrogenase 7.25 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 34 g/L; Total Protein 7.4 g/dL; Glucose 6.6 mmol/L.

Other clinical attributes
- Day 1: Weight: 107 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples)
- Sample MMRF_1433_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1433_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
- Sample MMRF_1433_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 883 days (2.4 years).
- Sample MMRF_1433_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 1,051 days (2.9 years).
